Somatic mutation profile of tumor specimen TCGA-NJ-A4YQ-01A (aliquot TCGA-NJ-A4YQ-01A-11D-A25L-08) from TCGA case TCGA-NJ-A4YQ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.6 years (25,427 days).
Specimen TCGA-NJ-A4YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 201b845c-183a-43b1-8fae-1cd17a3dcedd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A4YQ-10A (Blood Derived Normal), aliquot TCGA-NJ-A4YQ-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9b6674d-cad6-40bc-8902-036b8c1dfdc1

The open-access MAF lists 1,185 somatic variants for this specimen: 899 protein-altering or splice-affecting, 252 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 761, Silent 252, Nonsense Mutation 65, Frame Shift Del 34, Splice Site 26, Intron 14, RNA 12, Splice Region 9, 3'UTR 3, Frame Shift Ins 3, 5'Flank 3, 5'UTR 2.

Variants (750 of 1,185; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.5443G>T p.E1815* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as rs1451259945, COSV99268486; ClinVar: likely pathogenic; called by muse, varscan2
- SMARCA4 | c.3695G>T p.G1232V | Missense Mutation (SNP) | VAF 19/117 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60798111, COSV60802840; called by muse, mutect2, varscan2
- ABCA13 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as rs769670293, COSV101330005; called by mutect2, varscan2
- ABCG8 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99699658; called by muse, mutect2
- ABI3BP | c.980C>A p.P327H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV99426182; called by muse, mutect2, varscan2
- ACE | c.2565C>A p.Y855* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99326799; called by muse, mutect2, varscan2
- ACIN1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV99399434; called by muse, mutect2, varscan2
- ACSBG2 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV99397337; called by muse, mutect2, varscan2
- ACSL4 | c.718G>T p.E240* (on ENST00000340800 / NM_022977.2; = p.E199* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV100538457; called by muse, mutect2, varscan2
- ACTG2 | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV100609003; called by muse, mutect2, varscan2
- ACTL8 | c.591C>G p.C197W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100958582; called by muse, mutect2, varscan2
- ACTN3 | c.957C>A p.S319R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV101557827; called by muse, mutect2
- ADAM12 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900268; called by muse, mutect2, varscan2
- ADAM12 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100900271; called by muse, mutect2, varscan2
- ADAM19 | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.823); catalogued as COSV99976799; called by muse, mutect2, varscan2
- ADAM7 | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99443248; called by muse, mutect2, varscan2
- ADAMTS19 | c.3490+2T>A p.X1164_splice | Splice Site (SNP) | VAF 18/91 reads (20%) | catalogued as COSV99177183; called by muse, mutect2, varscan2
- ADAMTS2 | c.2675G>T p.R892L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV52376371; called by muse, mutect2, varscan2
- ADAMTS20 | c.2666A>G p.H889R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.339); catalogued as COSV101166193; called by muse, mutect2
- ADGRB3 | c.1795A>T p.T599S | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs768667380, COSV101000291, COSV101000292; called by muse, mutect2
- ADGRL2 | c.3424G>A p.D1142N (on ENST00000370717 / NM_001366005.1; = p.D1129N on NM_012302.4) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54691626, COSV99588253; called by muse, mutect2, varscan2
- AEBP1 | c.2291G>C p.G764A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99788649; called by muse, mutect2, varscan2
- AFP | c.261A>T p.L87F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV99889886; called by muse, mutect2, varscan2
- AHNAK2 | c.4958C>A p.A1653D | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1416591640, COSV100316905, COSV60922277; called by muse, mutect2
- AKAP12 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99482988; called by muse, mutect2, varscan2
- ALDH1L1 | c.2348-1G>C p.X783_splice | Splice Site (SNP) | VAF 22/125 reads (18%) | catalogued as COSV99856702; called by muse, mutect2, varscan2
- ALG10 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs924986686, COSV99848052; called by muse, mutect2, varscan2
- ALKBH8 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99508427, COSV99508661; called by muse, mutect2, varscan2
- ALPK3 | c.5015C>T p.P1672L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1244763962, COSV99360672; called by muse, mutect2, varscan2
- AMPH | c.1504G>T p.G502W | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100341675, COSV57754878; called by muse, mutect2, varscan2
- ANK1 | c.2008A>T p.T670S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99224792; called by muse, mutect2, varscan2
- ANK2 | c.2963G>T p.G988V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100000901; called by muse, mutect2, varscan2
- ANKIB1 | c.1637G>T p.W546L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99728821; called by muse, mutect2, varscan2
- ANKK1 | c.2052T>G p.N684K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100392788; called by muse, mutect2, varscan2
- ANKRD17 | c.4612A>T p.T1538S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100428910; called by muse, mutect2, varscan2
- ANKRD26 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs773171424, COSV101066215; called by muse, mutect2, varscan2
- ANXA2R | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.859); catalogued as rs754645658, COSV100148644; called by muse, mutect2
- AOX1 | c.1880T>A p.I627N | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101021881; called by muse, mutect2, varscan2
- APBA2 | c.2121C>A p.S707R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101382103; called by muse, mutect2, varscan2
- APOB | c.11088T>G p.I3696M | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV99264960; called by muse, mutect2, varscan2
- APOB | c.9290A>G p.K3097R | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.962); catalogued as COSV51938840, COSV99264964; called by muse, mutect2, varscan2
- ARFGEF2 | c.771G>T p.R257S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100904206; called by muse, mutect2, varscan2
- ARHGAP11A | c.2887G>T p.D963Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100276750; called by muse, mutect2, varscan2
- ARHGAP6 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.07); catalogued as COSV100272683; called by muse, mutect2, varscan2
- ARID1B | c.5507C>T p.P1836L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs202194222, COSV104368395, COSV99034207; called by muse, varscan2
- ARID3C | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs868822609, COSV100965855; called by muse, mutect2
- ARMC4 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99518466; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1534A>C p.N512H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100771874; called by muse, mutect2, varscan2
- ASTL | c.1163T>A p.L388Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV100668316; called by muse, mutect2, varscan2
- ASTN1 | c.1542A>G p.I514M | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV99921134; called by muse, mutect2, varscan2
- ASTN1 | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV56081649, COSV56085459; called by muse, mutect2, varscan2
- ATF7IP | c.1930-1G>T p.X644_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99661495; called by muse, mutect2, varscan2
- ATP10A | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100791087; called by muse, mutect2, varscan2
- ATP10B | c.539G>C p.C180S | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV100469312; called by muse, mutect2, varscan2
- ATP13A5 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as rs146780815, COSV100664992; called by muse, mutect2
- ATP2A3 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV99989040; called by muse, mutect2, varscan2
- ATP2B3 | c.1631A>T p.E544V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684018; called by muse, mutect2, varscan2
- ATP6V1G3 | c.276G>C p.M92I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99810766; called by muse, mutect2, varscan2
- ATP7B | c.4298T>G p.L1433R | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99666293; called by muse, mutect2
- ATRNL1 | c.2631T>A p.V877= | Splice Region (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100370159; called by muse, mutect2, varscan2
- ATRNL1 | c.2996C>A p.P999H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100370160; called by muse, mutect2, varscan2
- ATRNL1 | c.3499G>T p.G1167* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100370162; called by muse, mutect2
- ATXN2 | c.3323C>T p.P1108L (on ENST00000550104; = p.P948L on NM_002973.4) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101112693; called by muse, mutect2, varscan2
- AUTS2 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV100716119; called by muse, mutect2, varscan2
- B3GAT2 | c.653A>G p.E218G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100016822; called by muse, mutect2, varscan2
- BAHCC1 | c.6392C>T p.A2131V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs782345650, COSV100311465; called by muse, mutect2, varscan2
- BARHL2 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100966046; called by muse, mutect2, varscan2
- BAZ1A | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100701119; called by mutect2, varscan2
- BBOX1 | c.464C>G p.A155G | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99589585; called by muse, mutect2, varscan2
- BCLAF1 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100786557; called by muse, mutect2, varscan2
- BEND7 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.987); catalogued as COSV61987722; called by muse, mutect2, varscan2
- BIN2 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99530041; called by muse, varscan2
- BIN2 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99530042; called by muse, varscan2
- BMP15 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99399333; called by muse, mutect2, varscan2
- BMP2K | c.2414A>T p.D805V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV99785019; called by muse, mutect2, varscan2
- BMT2 | c.886G>C p.A296P | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51775462, COSV99774537; called by muse, mutect2, varscan2
- BNC1 | c.1336A>T p.T446S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV61759277; called by muse, mutect2
- BOD1L1 | c.6060A>T p.E2020D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99239018; called by muse, mutect2, varscan2
- BOD1L1 | c.3246G>T p.M1082I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99239020; called by muse, mutect2, varscan2
- BPI | c.1073C>A p.S358Y (on ENST00000262865; = p.S354Y on NM_001725.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.83); catalogued as COSV53407931, COSV99480537; called by muse, mutect2, varscan2
- BPTF | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs754887842, COSV58849172; called by muse, mutect2, varscan2
- BRCA1 | c.144G>C p.M48I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as CD129084, COSV100523845; called by muse, mutect2, varscan2
- BTN3A2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100709617; called by muse, mutect2
- C1orf210 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV70682529; called by muse, mutect2
- C1orf87 | c.1576C>A p.R526S | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100966997; called by muse, mutect2
- C4BPB | c.229C>A p.R77S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV99699960; called by muse, mutect2
- C6orf118 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); catalogued as COSV100024336; called by muse, mutect2
- CA12 | c.1010A>C p.N337T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV99458091; called by muse, mutect2, varscan2
- CABS1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV99909033; called by muse, mutect2
- CACNG6 | c.773G>T p.R258L (on ENST00000252729 / NM_145814.1; = p.R187L on NM_031897.2) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.045); catalogued as COSV53167208; called by muse, mutect2, varscan2
- CALHM2 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV99588479; called by muse, mutect2, varscan2
- CAMTA1 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100348310; called by muse, mutect2, varscan2
- CASS4 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100824613; called by muse, mutect2, varscan2
- CCDC141 | c.4325G>T p.W1442L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99836592; called by muse, mutect2
- CCDC178 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV100284397; called by muse, mutect2, varscan2
- CCDC190 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100905817; called by muse, mutect2
- CCDC190 | c.125A>T p.H42L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100905818; called by muse, mutect2
- CCDC40 | c.3158G>T p.R1053L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.346); catalogued as COSV100163100; called by muse, mutect2, varscan2
- CCDC88B | c.3449G>T p.R1150L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100105283; called by muse, mutect2, varscan2
- CCIN | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100631793, COSV100631951; called by muse, mutect2, varscan2
- CCNT2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99750494; called by muse, mutect2, varscan2
- CCP110 | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV101195250; called by muse, mutect2, varscan2
- CCT4 | c.322T>G p.S108A | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV101075152; called by muse, mutect2
- CD19 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100218083; called by muse, mutect2
- CD1B | c.571G>T p.V191F | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100939217, COSV63804283; called by muse, mutect2, varscan2
- CD1D | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV63809212; called by muse, mutect2
- CD55 | c.851G>T p.R284I | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.934); catalogued as COSV100132379; called by muse, mutect2, varscan2
- CDH18 | c.1754C>A p.T585N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99933755; called by muse, mutect2, varscan2
- CDH24 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99399432; called by muse, mutect2, varscan2
- CDK14 | c.462C>A p.S154R (on ENST00000380050 / NM_001287135.2; = p.S136R on NM_012395.3) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99724706; called by muse, mutect2, varscan2
- CDK19 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100098347; called by muse, mutect2, varscan2
- CDR1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV65164687; called by muse, varscan2
- CEMIP | c.559C>A p.R187S | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM034821, COSV99586523; called by muse, mutect2, varscan2
- CEP350 | c.3805G>A p.D1269N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV100854481; called by muse, mutect2
- CES5A | c.870G>T p.R290S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as rs369679321; called by muse, mutect2, varscan2
- CFAP299 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100811533, COSV63879071; called by muse, mutect2, varscan2
- CFAP52 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100235029; called by muse, mutect2, varscan2
- CFH | c.3385G>A p.A1129T | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV100809305; called by muse, mutect2, varscan2
- CHD8 | c.6507G>T p.Q2169H (on ENST00000646647 / NM_001170629.2; = p.Q1890H on NM_020920.4) | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100765276; called by muse, mutect2
- CHRM3 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.134); catalogued as rs200806862, COSV55093479, COSV99698033; called by muse, mutect2, varscan2
- CHRM5 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101271903; called by muse, mutect2, varscan2
- CHST10 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs773239496, COSV51807550, COSV99958862; called by muse, mutect2, varscan2
- CHST2 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100535926; called by muse, mutect2, varscan2
- CHSY3 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518878; called by muse, mutect2, varscan2
- CLCN1 | c.980-2A>T p.X327_splice | Splice Site (SNP) | VAF 17/117 reads (15%) | catalogued as COSV58375097; called by muse, mutect2, varscan2
- CLCN6 | c.2255C>A p.T752N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100411810; called by muse, mutect2, varscan2
- CLDN16 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV99290102; called by muse, mutect2, varscan2
- CLEC18B | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100375877; called by muse, mutect2
- CLUAP1 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100489608; called by muse, mutect2
- CNBD1 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101575282; called by muse, varscan2
- CNTFR | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1427918883, COSV100667512; called by muse, mutect2, varscan2
- CNTNAP2 | c.2785G>A p.G929S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.326); catalogued as rs755351132, COSV100665060, COSV100673046; called by muse, mutect2, varscan2
- CNTNAP2 | c.3185G>T p.C1062F | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100665062; called by muse, mutect2, varscan2
- CNTNAP5 | c.59A>C p.H20P | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV101420695; called by muse, mutect2, varscan2
- CNTNAP5 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV101443353; called by muse, mutect2, varscan2
- CNTNAP5 | c.3418T>G p.L1140V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101443354; called by muse, mutect2
- CNTNAP5 | c.3758G>T p.C1253F | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV101443355; called by muse, mutect2, varscan2
- COBL | c.2341G>C p.G781R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV99472163; called by muse, mutect2, varscan2
- COG7 | c.1888-1G>T p.X630_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100207505; called by muse, mutect2
- COL11A1 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV100615976; called by muse, mutect2, varscan2
- COL11A1 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV100615977; called by muse, mutect2, varscan2
- COL14A1 | c.5033G>T p.G1678V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918752; called by muse, mutect2, varscan2
- COL24A1 | c.4822C>T p.H1608Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV65306707; called by muse, mutect2, varscan2
- COL24A1 | c.846T>A p.D282E | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100993150; called by muse, mutect2, varscan2
- COL4A5 | c.2812G>T p.G938* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100087342; called by muse, mutect2, varscan2
- COL6A3 | c.6518C>T p.T2173I | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99797463; called by muse, mutect2, varscan2
- COL9A1 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294518; called by muse, mutect2, varscan2
- COQ9 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99345765; called by muse, mutect2, varscan2
- CORO2A | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100674011; called by muse, mutect2
- CPA2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.63); catalogued as rs1486933777, COSV99743947; called by muse, mutect2, varscan2
- CPA3 | c.739G>C p.G247R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936065; called by muse, mutect2, varscan2
- CPA5 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 27/178 reads (15%) | catalogued as COSV100812281; called by muse, mutect2, varscan2
- CPB1 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294184; called by muse, mutect2, varscan2
- CPQ | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766899037, COSV99611433; called by muse, mutect2, varscan2
- CPZ | c.282C>A p.N94K (on ENST00000360986 / NM_001014447.3; = p.N83K on NM_003652.3) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs199559782, COSV100248902; called by muse, mutect2, varscan2
- CR1 | c.3155C>A p.A1052D | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV100887526; called by muse, mutect2, varscan2
- CRAMP1 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99245863; called by muse, mutect2, varscan2
- CRHBP | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188337, COSV99169470; called by muse, mutect2
- CRX | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs193920917, COSV99704423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.7813C>T p.R2605* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV53962059; called by muse, mutect2, varscan2
- CSMD2 | c.7215G>T p.E2405D | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99588651; called by muse, mutect2, varscan2
- CSMD3 | c.9977C>A p.S3326* (on ENST00000297405 / NM_001363185.1; = p.S3157* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99831156; called by muse, mutect2, varscan2
- CSMD3 | c.1883A>T p.D628V (on ENST00000297405 / NM_001363185.1; = p.D524V on NM_052900.3) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99831157; called by muse, mutect2, varscan2
- CSNK2A1 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 15/223 reads (7%) | catalogued as COSV99424330; called by muse, mutect2
- CSRNP3 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV100085517, COSV58778076; called by muse, mutect2, varscan2
- CST2 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs202098615, COSV100491179; called by muse, mutect2, varscan2
- CSTF1 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV99410149; called by muse, mutect2, varscan2
- CSTL1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55678938, COSV99851118; called by muse, mutect2, varscan2
- CT55 | c.278A>T p.K93M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV99358840; called by muse, mutect2, varscan2
- CTSE | c.835G>T p.E279* (on ENST00000360218; = p.E274* on NM_001910.4) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100733606; called by muse, mutect2, varscan2
- CUX2 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99919315; called by muse, mutect2, varscan2
- CYLC2 | c.201A>T p.L67F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100872416; called by muse, mutect2, varscan2
- CYTIP | c.970A>T p.M324L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99938707; called by muse, mutect2
- CYYR1 | c.271C>G p.H91D | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100176823; called by muse, mutect2, varscan2
- DCAF12L2 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV63583574; called by muse, mutect2, varscan2
- DCAF4L2 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV60479690, COSV99081981; called by muse, mutect2, varscan2
- DCAF8 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.06); catalogued as COSV100470322, COSV58783120; called by muse, mutect2, varscan2
- DCAKD | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100149483, COSV60202664; called by muse, mutect2, varscan2
- DCDC1 | c.2986A>G p.R996G (on ENST00000597505 / NM_001367979.1; = p.R103G on NM_020869.3) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60311391; called by muse, mutect2, varscan2
- DCPS | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs756990032, COSV99703421; called by muse, mutect2, varscan2
- DCSTAMP | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52576012; called by muse, mutect2, varscan2
- DCSTAMP | c.995del p.P332Qfs*7 | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | catalogued as COSV99886873; called by mutect2, varscan2
- DDX5 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857842; called by muse, mutect2, varscan2
- DERL1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52365157; called by muse, mutect2, varscan2
- DGKI | c.1967G>C p.G656A | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99933561; called by muse, mutect2
- DHX15 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391304; called by muse, mutect2, varscan2
- DHX35 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99326703; called by muse, mutect2, varscan2
- DIDO1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV99825190; called by muse, mutect2, varscan2
- DISP3 | c.1979A>T p.Q660L | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99608171; called by muse, mutect2, varscan2
- DLGAP2 | c.1111T>A p.W371R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101421630; called by muse, mutect2
- DLK1 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100375162; called by mutect2, varscan2
- DLX5 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99756385, COSV99756676; called by muse, mutect2, varscan2
- DMD | c.6464G>T p.R2155L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV100626735; called by muse, mutect2, varscan2
- DNAH5 | c.9366A>C p.L3122F | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448129; called by muse, mutect2, varscan2
- DNAH5 | c.7993A>T p.N2665Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448133; called by muse, mutect2, varscan2
- DNAI4 | c.2053A>T p.I685F | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100925486; called by muse, mutect2
- DNAJC17 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99591609; called by muse, mutect2, varscan2
- DNMT3A | c.2570A>T p.D857V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99261581; called by muse, mutect2, varscan2
- DOCK2 | c.2443C>G p.L815V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99911523; called by muse, mutect2, varscan2
- DOCK2 | c.3683G>T p.R1228L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.105); catalogued as COSV99911526; called by muse, mutect2, varscan2
- DOCK2 | c.4466A>T p.Q1489L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV99911528; called by muse, mutect2, varscan2
- DOP1A | c.2821A>G p.R941G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99381586; called by muse, mutect2, varscan2
- DPEP2 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99263103; called by muse, mutect2, varscan2
- DPP10 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753076906, COSV100062444; called by muse, mutect2, varscan2
- DRD5 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs144132215, COSV58576684, COSV58579946; called by muse, mutect2, varscan2
- DRG2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as rs761322895, COSV99854879; called by muse, mutect2, varscan2
- DSEL | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025523; called by muse, mutect2, varscan2
- DST | c.19741C>T p.Q6581* (on ENST00000361203 / NM_001374722.1; = p.Q4278* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV99754184; called by muse, mutect2, varscan2
- DUOX1 | c.3877C>A p.Q1293K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.1); catalogued as COSV100367858, COSV58479958; called by muse, mutect2, varscan2
- DUSP22 | c.355C>A p.R119S | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100739650; called by muse, mutect2
- DYRK4 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50539575, COSV99155999; called by mutect2, varscan2
- DYTN | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); catalogued as COSV101123949; called by muse, mutect2, varscan2
- EDARADD | c.217C>T p.Q73* (on ENST00000334232 / NM_145861.4; = p.Q63* on NM_080738.4) | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100512679; called by muse, mutect2, varscan2
- EDARADD | c.481C>T p.Q161* (on ENST00000334232 / NM_145861.4; = p.Q151* on NM_080738.4) | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV100512681; called by muse, mutect2
- EDEM2 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV100788015, COSV100788039; called by muse, mutect2, varscan2
- EDIL3 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675807; called by muse, mutect2
- EDIL3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.026); catalogued as COSV99675810, COSV99676275; called by muse, mutect2, varscan2
- EDNRB | c.448G>T p.A150S (on ENST00000377211 / NM_001201397.1; = p.A60S on NM_000115.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV100526516; called by muse, mutect2, varscan2
- EIF2AK2 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99240570; called by muse, mutect2, varscan2
- EML3 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99605855; called by muse, mutect2, varscan2
- EMSY | c.2834A>G p.Q945R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.096); catalogued as rs1187466884, COSV100595589; called by muse, mutect2
- ENSA | c.122A>T p.Y41F | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as COSV99651269; called by muse, mutect2, varscan2
- EP300 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99608180; called by muse, mutect2, varscan2
- EPB41L3 | c.371G>C p.C124S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100548690; called by muse, mutect2, varscan2
- EPHA3 | c.2185G>T p.G729W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100344411; called by muse, mutect2, varscan2
- EPHA3 | c.2497-1G>T p.X833_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100344412, COSV60722186; called by mutect2, varscan2
- EPHA5 | c.2509-1G>T p.X837_splice | Splice Site (SNP) | VAF 19/133 reads (14%) | catalogued as COSV56635097; called by muse, mutect2, varscan2
- EPHA6 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175096670, COSV101061867; called by muse, mutect2, varscan2
- EPHB6 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101235965, COSV101235995; called by muse, mutect2, varscan2
- ERICH3 | c.2238G>T p.M746I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100443962; called by muse, mutect2, varscan2
- ETAA1 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99712692; called by muse, mutect2, varscan2
- EXOC3L1 | c.250T>G p.W84G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99333585; called by muse, mutect2, varscan2
- F12 | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53691060; called by muse, mutect2
- F13A1 | c.2104G>T p.G702W | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53559139, COSV99342704; called by muse, mutect2, varscan2
- FAM124B | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV99706284; called by muse, mutect2, varscan2
- FAM187B | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV100219982, COSV61200919; called by muse, mutect2, varscan2
- FAM47B | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100264248; called by muse, mutect2, varscan2
- FAM53C | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.028); catalogued as COSV99524312; called by muse, mutect2, varscan2
- FANCI | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as rs551399966, CM074785, COSV100167807; called by muse, mutect2, varscan2
- FBN2 | c.1244G>T p.R415I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV52503948, COSV99326521; called by muse, mutect2, varscan2
- FBN2 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV99326528; called by muse, mutect2
- FCN1 | c.916T>A p.W306R | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878874; called by muse, mutect2, varscan2
- FCRL5 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV100708782; called by muse, mutect2, varscan2
- FER1L6 | c.2510G>T p.G837V | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV101205730; called by muse, mutect2, varscan2
- FLG | c.11139G>T p.Q3713H | Missense Mutation (SNP) | VAF 62/513 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100911437; called by muse, mutect2, varscan2
- FLG | c.11138A>T p.Q3713L | Missense Mutation (SNP) | VAF 62/511 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV100911439; called by muse, mutect2, varscan2
- FLG2 | c.2128G>T p.G710W | Missense Mutation (SNP) | VAF 66/663 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101165780; called by muse, mutect2, varscan2
- FLNC | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100367920; called by muse, mutect2, varscan2
- FLRT2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 14/161 reads (9%) | catalogued as COSV100420246, COSV58138393; called by muse, mutect2
- FLT3 | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 17/119 reads (14%) | catalogued as COSV99608269; called by muse, mutect2, varscan2
- FLT4 | c.3113T>A p.L1038Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986596; called by muse, mutect2, varscan2
- FMN2 | c.2242C>A p.P748T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100144488; called by muse, mutect2, varscan2
- FNDC3B | c.2796G>C p.R932= | Splice Region (SNP) | VAF 26/117 reads (22%) | catalogued as COSV100393980; called by muse, mutect2, varscan2
- FOLR1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100398535; called by muse, mutect2, varscan2
- FOXJ2 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV50825706, COSV99368401; called by muse, mutect2, varscan2
- FOXP2 | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1563064505, COSV100646504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD2 | c.3469C>A p.Q1157K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100563733; called by muse, mutect2, varscan2
- FSIP2 | c.16490C>G p.A5497G | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV100554784; called by muse, mutect2, varscan2
- FYB1 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV100685242; called by muse, mutect2, varscan2
- FYB1 | c.318A>T p.K106N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as rs1376995961, COSV100685243; called by muse, mutect2, varscan2
- FZD10 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969359; called by muse, mutect2, varscan2
- GABRA6 | c.926T>A p.V309D | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194274; called by muse, mutect2, varscan2
- GABRG2 | c.164G>C p.W55S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100729642; called by muse, mutect2, varscan2
- GALNT7 | c.965+2T>A p.X322_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99397215; called by muse, varscan2
- GALNT8 | c.1174-1G>C p.X392_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99362703; called by muse, mutect2, varscan2
- GANAB | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100647964; called by muse, mutect2, varscan2
- GARNL3 | c.858A>C p.K286N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as COSV100150127; called by muse, mutect2, varscan2
- GATA3 | c.600C>G p.H200Q | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as COSV100650940; called by muse, mutect2, varscan2
- GBA3 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101545494, COSV101545549; called by muse, mutect2, varscan2
- GBP6 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100969519; called by muse, mutect2, varscan2
- GDPGP1 | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV100292033; called by muse, mutect2, varscan2
- GJA10 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV101005329, COSV65354758; called by muse, mutect2, varscan2
- GLI1 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1285900168, COSV57364835, COSV99953982; called by muse, mutect2, varscan2
- GLI2 | c.3824C>A p.P1275H (on ENST00000361492 / NM_001374353.1; = p.P1292H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as COSV100082883; called by muse, mutect2, varscan2
- GLI3 | c.3670G>T p.G1224C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV101229816, COSV67887844; called by muse, mutect2, varscan2
- GLP2R | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV52327023; called by muse, mutect2, varscan2
- GP5 | c.227T>G p.L76R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99756817; called by muse, mutect2
- GP5 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV99756819; called by muse, mutect2
- GPCPD1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100980142; called by muse, mutect2, varscan2
- GPI | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99874964; called by muse, mutect2, varscan2
- GPNMB | c.1066G>T p.D356Y (on ENST00000381990 / NM_001005340.2; = p.D344Y on NM_002510.3) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99326425; called by muse, mutect2, varscan2
- GRAMD1B | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV100454584, COSV59208899; called by muse, mutect2, varscan2
- GRB7 | c.295A>T p.S99C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV100485450; called by muse, mutect2, varscan2
- GRIK2 | c.2299G>T p.G767C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024988; called by muse, mutect2
- GSX2 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100482548; called by muse, mutect2, varscan2
- GTF3C1 | c.3488G>T p.R1163L | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100649258; called by muse, mutect2, varscan2
- GUCY1A2 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99974071; called by muse, mutect2, varscan2
- GYG2 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs764509996, COSV100088869; called by muse, mutect2, varscan2
- HACE1 | c.1550A>T p.H517L | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV99493533; called by muse, mutect2, varscan2
- HAS2 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 28/199 reads (14%) | catalogued as COSV100391658, COSV58265707; called by muse, varscan2
- HDC | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99983946; called by muse, mutect2, varscan2
- HECTD4 | c.5123G>C p.R1708P | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101107220, COSV66397062; called by muse, mutect2, varscan2
- HECW1 | c.172_173insT p.H58Lfs*14 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | catalogued as COSV101223258; called by mutect2, pindel, varscan2
- HEPH | c.2737G>A p.G913R (on ENST00000343002; = p.G646R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100294614; called by muse, mutect2, varscan2
- HFM1 | c.3008C>A p.A1003E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as COSV54037270; called by muse, mutect2, varscan2
- HGF | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 51/97 reads (53%) | catalogued as COSV99736465; called by muse, mutect2, varscan2
- HK3 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV99458286; called by muse, mutect2, varscan2
- HLA-DQB1 | c.554G>T p.W185L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs9273961, COSV100891178; called by muse, mutect2, varscan2
- HMCN1 | c.5338G>C p.G1780R | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV99627484; called by muse, mutect2
- HMGCS2 | c.968C>G p.A323G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101024761; called by muse, mutect2, varscan2
- HNF4A | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV100291295; called by muse, mutect2
- HNRNPA3 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101182895; called by muse, mutect2, varscan2
- HOXB13 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51704205, COSV99284840; called by muse, mutect2
- HOXB2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100344553; called by muse, mutect2, varscan2
- HRNR | c.6220G>T p.G2074W | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1394865580, COSV100913302; called by muse, mutect2, varscan2
- HRNR | c.5633C>A p.S1878* | Nonsense Mutation (SNP) | VAF 56/2287 reads (2%) | catalogued as COSV100913303, COSV64263746; called by muse, mutect2
- HRNR | c.3133G>T p.G1045C | Missense Mutation (SNP) | VAF 109/537 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV100913304, COSV64253745; called by muse, mutect2, varscan2
- HSPA6 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100554075; called by muse, mutect2
- HTR5A | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99839612; called by muse, mutect2, varscan2
- HTRA1 | c.1118A>T p.K373I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100934729; called by muse, mutect2
- IARS1 | c.2534A>G p.Y845C | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as rs1385804076, COSV100986690; called by muse, mutect2, varscan2
- ICOS | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.466); catalogued as COSV100320307; called by muse, mutect2, varscan2
- IFFO1 | c.1091G>A p.R364Q (on ENST00000396840 / NM_001330324.2; = p.R367Q on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs374531073; called by muse, mutect2, varscan2
- IFT172 | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99562181; called by muse, mutect2, varscan2
- IGF2R | c.6925G>T p.V2309L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100807209; called by muse, mutect2, varscan2
- IGHMBP2 | c.2812G>T p.A938S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV99661887, COSV99661992; called by muse, mutect2, varscan2
- IGSF10 | c.2223G>T p.R741S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV56782319, COSV99178760; called by muse, mutect2, varscan2
- IGSF22 | c.2146G>T p.A716S (on ENST00000319338; = p.A817S on NM_173588.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100079519; called by muse, mutect2, varscan2
- IKBIP | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV100689751; called by muse, mutect2, varscan2
- IKBKB | c.1542G>C p.W514C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100645658, COSV60597517; called by muse, mutect2, varscan2
- IKZF1 | c.870C>G p.D290E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100498290; called by muse, mutect2
- IL12RB1 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1568514893, COSV59096913; called by muse, mutect2, varscan2
- IL21R | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100560015; called by muse, mutect2, varscan2
- INSM2 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.039); catalogued as COSV99354206; called by muse, mutect2, varscan2
- INSR | c.3197G>T p.R1066L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100251932; called by muse, mutect2, varscan2
- INSRR | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100947373; called by muse, mutect2, varscan2
- INSRR | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100947374, COSV63872335; called by muse, mutect2, varscan2
- IP6K3 | c.376T>G p.W126G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.703); catalogued as COSV99539741; called by muse, mutect2, varscan2
- IPO9 | c.1772G>T p.C591F | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100843386; called by muse, mutect2, varscan2
- IPPK | c.1413C>A p.N471K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as COSV55332969, COSV99845546; called by muse, mutect2, varscan2
- IQCN | c.3097T>A p.C1033S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100828240; called by muse, mutect2, varscan2
- IQGAP2 | c.3663C>A p.L1221= | Splice Region (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99166990; called by muse, mutect2, varscan2
- IRF4 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV101110824; called by muse, mutect2, varscan2
- ITFG1 | c.1838G>T p.*613Lext*7 | Nonstop Mutation (SNP) | VAF 21/178 reads (12%) | catalogued as COSV100278617; called by muse, mutect2, varscan2
- ITGAL | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV100776193; called by muse, mutect2, varscan2
- ITGAX | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191603; called by muse, mutect2
- ITSN2 | c.1943A>T p.K648M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100743173; called by muse, mutect2, varscan2
- JAKMIP1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99289237; called by muse, mutect2
- KANSL1L | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99910404; called by muse, mutect2, varscan2
- KCNA3 | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871236, COSV63901810; called by muse, mutect2, varscan2
- KCNH7 | c.1508C>A p.A503E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100035188; called by muse, mutect2, varscan2
- KCNQ2 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100610044; called by muse, mutect2
- KCNQ3 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV101195901; called by muse, mutect2, varscan2
- KCNT2 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99652869; called by muse, mutect2, varscan2
- KDM2B | c.1841G>T p.R614L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1555292064, COSV100997356, COSV100997407; called by muse, mutect2
- KDR | c.527G>T p.R176I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99817309; called by muse, mutect2
- KEAP1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); catalogued as COSV50331039, COSV99407625; called by muse, mutect2, varscan2
- KIAA1549L | c.3107C>T p.P1036L (on ENST00000321505; = p.P1333L on NM_012194.3) | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747075827, COSV55771283; called by muse, mutect2, varscan2
- KIF21B | c.3667T>C p.Y1223H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.691); catalogued as COSV100144304; called by muse, mutect2, varscan2
- KIF26B | c.2143T>A p.C715S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100832085; called by muse, mutect2, varscan2
- KIF5C | c.1401G>C p.Q467H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101276119; called by muse, mutect2
- KIFC1 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100996046; called by muse, mutect2, varscan2
- KLHL14 | c.1756A>G p.K586E | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100839136; called by muse, mutect2, varscan2
- KLHL5 | c.1663+1G>T p.X555_splice | Splice Site (SNP) | VAF 12/98 reads (12%) | catalogued as rs755006031, COSV99785123; called by muse, mutect2, varscan2
- KLK11 | c.558G>T p.Q186H (on ENST00000594768 / NM_144947.3; = p.Q154H on NM_006853.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs900264581, COSV100011038; called by muse, mutect2, varscan2
- KMO | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100844799; called by muse, mutect2
- KMT2D | c.5012G>T p.S1671I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99979992; called by muse, mutect2, varscan2
- KRBA1 | c.2410C>A p.H804N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99752523; called by muse, mutect2, varscan2
- KRT12 | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99288894; called by muse, mutect2, varscan2
- KRT14 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99390965; called by muse, mutect2, varscan2
- KRT6A | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV58108664; called by muse, mutect2, varscan2
- KRT6A | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV100416880; called by muse, mutect2, varscan2
- KRT7 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs775486914, COSV100081463; called by muse, mutect2, varscan2
- KRT79 | c.1338C>A p.Y446* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100398397; called by muse, mutect2, varscan2
- KRT83 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99531542; called by muse, mutect2, varscan2
- LAMA2 | c.1366T>A p.C456S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101370345; called by muse, mutect2, varscan2
- LAMA4 | c.3110G>T p.R1037L (on ENST00000230538 / NM_001105206.3; = p.R1030L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201939337, COSV100038135; called by muse, mutect2, varscan2
- LAMC3 | c.2745G>T p.R915= | Splice Region (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100735946; called by muse, mutect2, varscan2
- LAMP5 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99855533; called by muse, mutect2, varscan2
- LARP1 | c.1245C>G p.F415L (on ENST00000518297 / NM_033551.3; = p.F338L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100303680; called by muse, mutect2
- LATS2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV101231524; called by muse, mutect2, varscan2
- LCE2A | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV100909142; called by muse, mutect2, varscan2
- LCE2C | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100909418, COSV64228499; called by muse, mutect2, varscan2
- LCE5A | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.013); catalogued as COSV100524223; called by muse, mutect2, varscan2
- LDLRAD3 | c.627C>A p.H209Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV100214480; called by muse, mutect2, varscan2
- LGALSL | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV99482428; called by muse, mutect2
- LIN28A | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs1167783843, COSV99575291; called by muse, mutect2, varscan2
- LIN7A | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV99691957; called by muse, mutect2, varscan2
- LRFN2 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57832172; called by muse, mutect2
- LRIT2 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258733, COSV60564680; called by muse, mutect2, varscan2
- LRP1B | c.10446G>T p.Q3482H | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV101255260; called by muse, mutect2, varscan2
- LRP1B | c.7280C>T p.A2427V | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV101252701; called by muse, mutect2, varscan2
- LRP1B | c.3244G>T p.G1082C | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101255263; called by muse, mutect2, varscan2
- LRP2 | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99787684; called by muse, mutect2, varscan2
- LRP8 | c.1454del p.P485Rfs*110 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as COSV60096742; called by mutect2, pindel
- LRRC15 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100752653; called by muse, mutect2
- LRRC8C | c.2019G>T p.E673D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100968195; called by muse, mutect2, varscan2
- LVRN | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs778641858, COSV100773401; called by muse, mutect2, varscan2
- MACF1 | c.17472G>T p.R5824S (on ENST00000372915; = p.R3866S on NM_012090.5) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99243324; called by muse, mutect2, varscan2
- MAEL | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100901794; called by muse, mutect2, varscan2
- MAEL | c.1133G>T p.R378M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100901796, COSV100902020; called by muse, mutect2, varscan2
- MAEL | c.1134G>T p.R378S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100901799; called by muse, mutect2, varscan2
- MAGEB10 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV100775235; called by muse, mutect2, varscan2
- MAGEB18 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.532); catalogued as COSV100305409; called by muse, mutect2, varscan2
- MAGEB18 | c.797G>C p.R266P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV57463648; called by muse, mutect2, varscan2
- MAGEC1 | c.2302del p.E768Rfs*20 | Frame Shift Del (DEL) | VAF 37/298 reads (12%) | catalogued as COSV99596826; called by mutect2, pindel, varscan2
- MAGEC1 | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1365359013, COSV99595395; called by muse, mutect2, varscan2
- MAGEC2 | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55999248, COSV99909528; called by muse, mutect2, varscan2
- MAMLD1 | c.2017G>A p.G673R | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99475802; called by muse, mutect2, varscan2
- MANBA | c.570G>T p.W190C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56963252, COSV99898561; called by muse, mutect2, varscan2
- MAP1B | c.2398G>T p.G800C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV99702156; called by muse, mutect2, varscan2
- MAP7 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 56/432 reads (13%) | catalogued as COSV100643825; called by muse, mutect2, varscan2
- MAPK12 | c.314T>A p.F105Y | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99299251; called by muse, mutect2
- MAPK9 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs778148482, COSV100558264; called by muse, mutect2, varscan2
- MAPKAPK5 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV101612880; called by muse, mutect2, varscan2
- MARCHF11 | c.540T>A p.G180= | Splice Region (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100197726; called by muse, mutect2, varscan2
- MARK3 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.89); catalogued as COSV99358125; called by muse, mutect2, varscan2
- MC5R | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229003; called by muse, varscan2
- MC5R | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV61255786; called by muse, varscan2
- MCM3 | c.1909G>T p.A637S (on ENST00000229854 / NM_001366374.2; = p.A627S on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV57717998; called by muse, mutect2, varscan2
- MDM1 | c.1452G>C p.E484D | Missense Mutation (SNP) | VAF 35/578 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100291769, COSV57449015; called by muse, mutect2
- ME3 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100660914, COSV62774717; called by muse, mutect2, varscan2
- MED12L | c.5978G>T p.S1993I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV99852516; called by muse, mutect2, varscan2
- MED13L | c.2372G>T p.R791I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV99928488; called by muse, mutect2, varscan2
- MEI1 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.875); catalogued as COSV100299828; called by muse, mutect2, varscan2
- MEIS2 | c.1036+1G>T p.X346_splice (on ENST00000561208 / NM_170675.5; = p.X333_splice on NM_002399.3) | Splice Site (SNP) | VAF 14/120 reads (12%) | catalogued as COSV54936103; called by muse, mutect2, varscan2
- MFSD11 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100333752; called by muse, mutect2, varscan2
- MGAT3 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.929); catalogued as COSV100361830; called by muse, mutect2, varscan2
- MIA2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV99697513; called by muse, mutect2, varscan2
- MICAL1 | c.2441A>C p.Q814P | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as COSV99237911; called by muse, varscan2
- MIER3 | c.949T>C p.C317R (on ENST00000381199 / NM_001297599.2; = p.C316R on NM_152622.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101167567; called by muse, mutect2
- MIOS | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100402673; called by muse, mutect2, varscan2
- MMP11 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99303164; called by muse, mutect2, varscan2
- MOGAT1 | c.645G>T p.L215F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV101485109, COSV101485121; called by mutect2, varscan2
- MORC1 | c.2085+1G>A p.X695_splice | Splice Site (SNP) | VAF 45/349 reads (13%) | catalogued as COSV99225711; called by muse, mutect2, varscan2
- MSH2 | c.1478A>T p.Q493L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs376990143, COSV51881744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH2 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99253630; called by muse, mutect2, varscan2
- MTCH1 | c.513+2T>A p.X171_splice | Splice Site (SNP) | VAF 18/86 reads (21%) | catalogued as COSV101010171; called by muse, mutect2, varscan2
- MTERF3 | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 17/156 reads (11%) | catalogued as COSV99749690; called by muse, mutect2, varscan2
- MTRR | c.1597C>A p.H533N (on ENST00000264668; = p.H506N on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99241561; called by muse, mutect2, varscan2
- MTRR | c.2087G>T p.S696I (on ENST00000264668; = p.S669I on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV99241564; called by muse, mutect2, varscan2
- MYCBP2 | c.4376G>A p.C1459Y (on ENST00000357337; = p.C1497Y on NM_015057.5) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100629934; called by muse, mutect2
- MYEF2 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99981425; called by muse, mutect2, varscan2
- MYF5 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99953230; called by muse, mutect2, varscan2
- MYF5 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99953231; called by muse, mutect2, varscan2
- MYH8 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs759476464, COSV101238361; called by muse, mutect2
- MYL7 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99789962; called by muse, mutect2, varscan2
- MYO10 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57021668, COSV99945145; called by muse, mutect2, varscan2
- MYO15A | c.1266C>G p.H422Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99232199; called by muse, mutect2, varscan2
- MYO7A | c.2173A>T p.K725* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | catalogued as COSV101289098; called by muse, mutect2, varscan2
- MYO7B | c.2223del p.K742Rfs*6 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as COSV101267841; called by mutect2, pindel, varscan2
- MYO9A | c.5446G>T p.G1816C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100613157, COSV61848168; called by muse, mutect2
- MYOC | c.1264C>A p.R422S | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99231426; called by muse, mutect2, varscan2
- MYT1L | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101220069; called by muse, mutect2, varscan2
- N4BP1 | c.2281G>T p.G761* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99285045; called by muse, mutect2, varscan2
- NCAM1 | c.1609G>T p.G537W (on ENST00000316851 / NM_181351.5; = p.G527W on NM_000615.7) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57514194; called by muse, mutect2, varscan2
- NCAM1 | c.1610G>T p.G537V (on ENST00000316851 / NM_181351.5; = p.G527V on NM_000615.7) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57514214; called by muse, mutect2, varscan2
- NCKAP1 | c.2929G>C p.V977L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.069); catalogued as rs775898947, COSV100720154; called by muse, mutect2, varscan2
- NCR1 | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV99400865; called by muse, mutect2, varscan2
- NDST3 | c.1230C>A p.H410Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.419); catalogued as COSV99630190, COSV99631538, COSV99631897; called by muse, mutect2, varscan2
- NET1 | c.1038A>G p.I346M (on ENST00000355029 / NM_001047160.3; = p.I292M on NM_005863.5) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100742260; called by muse, mutect2, varscan2
- NFASC | c.1304C>A p.P435H (on ENST00000339876 / NM_001378329.1; = p.P446H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100363457; called by muse, mutect2
- NID1 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV99937342; called by muse, mutect2, varscan2
- NID1 | c.525+2T>A p.X175_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99937347; called by muse, mutect2
- NIPAL4 | c.1379A>T p.K460I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV99976796; called by mutect2, varscan2
- NLGN4X | c.1415T>C p.F472S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321145; called by muse, mutect2, varscan2
- NLRP5 | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101173551, COSV66765761; called by muse, mutect2, varscan2
- NOD1 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99767970; called by muse, mutect2, varscan2
- NOL4 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99305960, COSV99308523; called by muse, mutect2, varscan2
- NRCAM | c.589G>A p.G197S (on ENST00000379028 / NM_001371124.1; = p.G191S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.731); catalogued as COSV100694555; called by muse, mutect2, varscan2
- NRG1 | c.1346del p.P449Lfs*11 (on ENST00000405005 / NM_013964.5; = p.P454Lfs*11 on NM_013956.5) | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as COSV99830113; called by mutect2, pindel, varscan2
- NRXN1 | c.3331A>T p.M1111L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV100454414; called by muse, mutect2
- NT5C1A | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99348384; called by muse, mutect2, varscan2
- NUF2 | c.653A>G p.E218G | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs965096502, COSV99616355; called by muse, mutect2
- NUP153 | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100020145; called by muse, mutect2, varscan2
- NYNRIN | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV101230565; called by muse, mutect2, varscan2
- OAS2 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100660093, COSV100660218; called by muse, mutect2
- OBSCN | c.3567G>T p.E1189D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as COSV99476214; called by muse, mutect2, varscan2
- OCA2 | c.513G>T p.L171= | Splice Region (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100667411; called by muse, mutect2
- OGDHL | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV65101253; called by muse, mutect2, varscan2
- OMD | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100979038; called by muse, mutect2, varscan2
- ONECUT2 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV101525701; called by muse, mutect2, varscan2
- OR10H4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 82/393 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs372856114; called by muse, mutect2, varscan2
- OR10J5 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100604657; called by muse, mutect2
- OR10K1 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV99193417; called by muse, mutect2
- OR10X1 | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752248137, COSV100936625; called by muse, mutect2, varscan2
- OR11G2 | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100639937; called by muse, mutect2, varscan2
- OR11H6 | c.487G>T p.V163F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100209772; called by muse, mutect2
- OR14C36 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100507489, COSV58602732; called by muse, mutect2, varscan2
- OR1C1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.145); catalogued as COSV101376212, COSV68716464; called by muse, mutect2, varscan2
- OR1N2 | c.677G>C p.W226S | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1172593993, COSV101031376, COSV65460990; called by muse, mutect2, varscan2
- OR2A25 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV101376372; called by muse, mutect2, varscan2
- OR2B11 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100275756, COSV100276452, COSV59510571; called by muse, mutect2
- OR2G2 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.789); catalogued as COSV100189701; called by muse, varscan2
- OR2G6 | c.274A>G p.M92V | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100598100; called by muse, mutect2, varscan2
- OR2G6 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58574332; called by muse, mutect2, varscan2
- OR2L3 | c.526T>A p.F176I | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV100741952; called by muse, mutect2, varscan2
- OR2L8 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV100594119; called by muse, mutect2, varscan2
- OR2L8 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931885996, COSV100594122, COSV61726113; called by muse, mutect2, varscan2
- OR2M2 | c.60C>A p.H20Q | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV100677216, COSV99080686; called by muse, mutect2
- OR2M4 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs763034260, COSV100141124; called by muse, mutect2, varscan2
- OR2M5 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs368493003, COSV100822766; called by muse, mutect2
- OR2M7 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100522494, COSV58740012; called by muse, mutect2, varscan2
- OR2T12 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV100527692; called by muse, mutect2, varscan2
- OR2T27 | c.678T>A p.Y226* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100788201; called by muse, varscan2
- OR2T3 | c.621C>A p.C207* | Nonsense Mutation (SNP) | VAF 40/430 reads (9%) | catalogued as COSV62082480, COSV62083087; called by muse, mutect2
- OR2T33 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100531787; called by muse, mutect2, varscan2
- OR2T33 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV58816268; called by muse, mutect2, varscan2
- OR2T4 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63544483; called by muse, mutect2, varscan2
- OR4C16 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100113994; called by muse, mutect2, varscan2
- OR4C46 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV100060590; called by muse, mutect2, varscan2
- OR4C46 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs775007149, COSV60218688; called by muse, mutect2, varscan2
- OR4C6 | c.548T>A p.L183* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as COSV100051554; called by muse, mutect2, varscan2
- OR4D2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV101613850; called by muse, mutect2, varscan2
- OR4K1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV99578851; called by muse, mutect2
- OR4L1 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100235643; called by muse, mutect2, varscan2
- OR4N2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 32/399 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV60049827; called by muse, mutect2
- OR4P4 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.039); catalogued as rs765931099, COSV100111675; called by muse, mutect2, varscan2
- OR4Q3 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100056939; called by muse, mutect2, varscan2
- OR52E6 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as COSV100259268; called by muse, mutect2, varscan2
- OR52I2 | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100442882; called by muse, mutect2, varscan2
- OR5M10 | c.883A>T p.R295* | Nonsense Mutation (SNP) | VAF 53/351 reads (15%) | catalogued as COSV101595878; called by muse, mutect2, varscan2
- OR5P2 | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs1188839155, COSV100271287; called by muse, mutect2, varscan2
- OR5T1 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as COSV100478893; called by muse, varscan2
- OR6K2 | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62743269; called by muse, mutect2, varscan2
- OR6N1 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as COSV58647345, COSV58650137; called by muse, mutect2
- OR8A1 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV52510521, COSV99420501; called by muse, mutect2, varscan2
- OR8G1 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV100422360; called by muse, mutect2
- OR8H1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100477006; called by muse, mutect2, varscan2
- OR8U1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775620308, COSV100163864; called by muse, mutect2
- OSBPL9 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543236; called by muse, mutect2
- OTC | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV99234069; called by muse, mutect2, varscan2
- OTOF | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717269; called by muse, mutect2, varscan2
- OTOP1 | c.1127A>T p.E376V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV99587566; called by muse, mutect2, varscan2
- OTUD7A | c.1556C>A p.S519Y (on ENST00000307050 / NM_001382637.1; = p.S512Y on NM_130901.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100192293; called by muse, mutect2, varscan2
- OXER1 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV99685336; called by muse, mutect2, varscan2
- PABPC1L | c.670A>T p.R224W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); catalogued as COSV99407725; called by muse, mutect2, varscan2
- PAK3 | c.1676G>T p.R559L (on ENST00000262836 / NM_001324328.2; = p.R544L on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53276325, COSV99457053; called by muse, mutect2, varscan2
- PALLD | c.1335+1G>T p.X445_splice | Splice Site (SNP) | VAF 20/147 reads (14%) | catalogued as rs756057934, COSV54986335; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1610G>T p.G537V (on ENST00000259318 / NM_001136562.3; = p.G768V on NM_007203.5) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.058); catalogued as COSV99395049; called by muse, mutect2, varscan2
- PAPPA | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100073645; called by muse, mutect2
- PAX8 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54511715; called by muse, mutect2, varscan2
- PAXIP1 | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV101249563; called by muse, mutect2
- PBX1 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100905027, COSV100905198; called by muse, mutect2, varscan2
- PCDH7 | c.3095G>C p.G1032A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV100688008; called by muse, mutect2, varscan2
- PCDHA1 | c.1841C>A p.A614E | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV65374669; called by muse, mutect2, varscan2
- PCDHA8 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV65340295; called by muse, mutect2
- PCDHAC1 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV99165693; called by muse, mutect2, varscan2
- PCDHB11 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 26/238 reads (11%) | catalogued as rs782173189, COSV99504081; called by muse, mutect2, varscan2
- PCDHB11 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV99504082; called by muse, mutect2, varscan2
- PCDHB15 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51043695, COSV99178884; called by muse, mutect2, varscan2
- PCDHB15 | c.1828A>T p.T610S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV99178885; called by muse, mutect2, varscan2
- PCDHB16 | c.2045A>T p.Q682L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV99501757; called by muse, mutect2, varscan2
- PCDHB5 | c.1059C>A p.S353R | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); catalogued as COSV99167816; called by muse, mutect2, varscan2
- PCDHB6 | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.145); catalogued as COSV99170048; called by muse, mutect2
- PCDHB7 | c.1972C>A p.L658M | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV50764877, COSV99176775; called by muse, mutect2
- PCDHGA1 | c.1918C>A p.Q640K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV100965977; called by muse, mutect2, varscan2
- PCDHGA2 | c.881T>A p.L294H | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99535527; called by muse, mutect2
- PCDHGA2 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53912909; called by muse, mutect2, varscan2
- PCDHGA9 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99535537; called by muse, mutect2
- PCDHGA9 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.251); catalogued as rs1459982001, COSV53915094; called by muse, mutect2, varscan2
- PCDHGB1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV53942197; called by muse, mutect2
- PCDHGB1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV99535528; called by muse, mutect2, varscan2
- PCDHGB1 | c.2221G>T p.E741* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | catalogued as COSV53901777, COSV99535530; called by muse, mutect2, varscan2
- PCYOX1L | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.234); catalogued as rs775253723, COSV99199172; called by muse, mutect2, varscan2
- PDE6A | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99678134; called by muse, varscan2
- PDZD2 | c.8122A>T p.M2708L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99224607; called by muse, mutect2, varscan2
- PDZD4 | c.1107C>A p.N369K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99381231; called by muse, mutect2, varscan2
- PDZD9 | c.450T>G p.S150R (on ENST00000424898 / NM_001363519.1; = p.S90R on NM_173806.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV99193293; called by muse, mutect2, varscan2
- PDZRN3 | c.2435C>A p.T812K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV55210398, COSV99728892; called by muse, mutect2, varscan2
- PEAK1 | c.4603G>T p.G1535C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100432812; called by muse, mutect2, varscan2
- PERP | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1238585676, COSV101408585; called by muse, mutect2, varscan2
- PGBD2 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558289990, COSV100251973; called by muse, mutect2
- PGGHG | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV67141158; called by muse, mutect2, varscan2
- PIBF1 | c.1489-1G>T p.X497_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100411391; called by mutect2, varscan2
- PIBF1 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs780730535, COSV100411393; called by mutect2, varscan2
- PIK3CG | c.2074G>T p.G692C | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63248129; called by muse, mutect2, varscan2
- PIP5K1B | c.265T>A p.L89I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99598549; called by muse, mutect2, varscan2
- PJA2 | c.1195G>T p.G399* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100754379; called by muse, mutect2, varscan2
- PLOD3 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777944; called by muse, mutect2, varscan2
- PLPPR4 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV100926761; called by muse, mutect2, varscan2
- PLXNA2 | c.3387G>T p.L1129F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100885328; called by muse, mutect2
- PLXNA4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as COSV100323695; called by muse, mutect2, varscan2
- PLXND1 | c.5662-1G>T p.X1888_splice | Splice Site (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100139493; called by muse, mutect2, varscan2
- PM20D1 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs375544300, COSV100900162; called by muse, mutect2, varscan2
- POP1 | c.2809G>T p.V937L | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as COSV100855745; called by muse, mutect2, varscan2
- POTEF | c.172A>T p.R58W | Missense Mutation (SNP) | VAF 47/406 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); catalogued as COSV100664769; called by muse, mutect2, varscan2
- PPARGC1A | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs776120045, COSV53524891, COSV53526826; called by muse, mutect2, varscan2
- PPARGC1B | c.2272C>A p.H758N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV100494651; called by muse, mutect2, varscan2
- PPP2R1A | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100436202; called by muse, mutect2, varscan2
- PRAMEF12 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs745324749, COSV100742977, COSV100743171; called by muse, mutect2, varscan2
- PRDM14 | c.970T>A p.W324R | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99400049; called by muse, mutect2, varscan2
- PRDM5 | c.904A>T p.K302* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99310342; called by muse, mutect2, varscan2
- PRR16 | c.704G>A p.S235N (on ENST00000407149 / NM_001300783.2; = p.S212N on NM_016644.2) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV101086848; called by muse, mutect2, varscan2
- PRSS35 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV100864078; called by muse, mutect2, varscan2
- PRSS36 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99191254; called by muse, mutect2, varscan2
- PRSS38 | c.122A>C p.Q41P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100816454; called by mutect2, varscan2
- PRTG | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV101221348; called by muse, mutect2, varscan2
- PRUNE2 | c.2021G>T p.S674I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100944438; called by mutect2, varscan2
- PSCA | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100008217; called by muse, mutect2, varscan2
- PSD4 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99831018; called by muse, mutect2, varscan2
- PTAFR | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100544331; called by muse, mutect2, varscan2
- PTCHD4 | c.1327C>A p.H443N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1209038000, COSV100260564; called by muse, mutect2, varscan2
- PTPN22 | c.114C>A p.Y38* | Nonsense Mutation (SNP) | VAF 12/153 reads (8%) | catalogued as COSV100703538; called by muse, mutect2
- PTPRB | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs748496044, COSV100546822; called by mutect2, varscan2
- PTPRK | c.2639A>T p.K880M (on ENST00000368215 / NM_001291984.2; = p.K881M on NM_002844.4) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100950789; called by muse, mutect2, varscan2
- PTPRT | c.2023G>T p.V675F | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV100626554; called by muse, mutect2, varscan2
- PTPRZ1 | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101099923; called by muse, mutect2, varscan2
- PTPRZ1 | c.5360A>C p.Y1787S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101099924; called by muse, mutect2, varscan2
- PTPRZ1 | c.6329T>C p.I2110T | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101099926; called by muse, mutect2, varscan2
- PWWP3B | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100531127; called by muse, mutect2, varscan2
- PYCR2 | c.457A>T p.M153L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100661501; called by muse, mutect2, varscan2
- QKI | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV99274810; called by muse, mutect2, varscan2
- R3HDM1 | c.1205G>T p.R402M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99926045; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1475G>T p.G492V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV99241897; called by muse, mutect2, varscan2
- RABEP1 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99336488; called by muse, mutect2, varscan2
- RAD54L2 | c.1911G>T p.L637F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV99621062; called by muse, mutect2, varscan2
- RALGDS | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as rs756620107, COSV100924376; called by muse, mutect2
- RAMP3 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.477); catalogued as COSV99642222; called by muse, mutect2
- RANBP10 | c.1390A>C p.N464H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100449245; called by muse, mutect2, varscan2
- RAPGEF1 | c.2144A>T p.Y715F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.739); catalogued as COSV100940441; called by muse, mutect2, varscan2
- RAPGEF6 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.759); catalogued as COSV99726117; called by muse, mutect2, varscan2
- RAVER2 | c.275A>C p.Y92S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99605047; called by muse, mutect2, varscan2
- RBFOX1 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432730510, COSV100300747; called by muse, mutect2, varscan2
- REG3A | c.148C>G p.H50D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as rs747395684, COSV100532643, COSV100532800, COSV59408769; called by muse, mutect2
- RELN | c.4901C>T p.S1634F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100633253; called by muse, mutect2, varscan2
- REXO2 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99771720; called by muse, varscan2
- REXO5 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99759118; called by muse, mutect2, varscan2
- RGS12 | c.4025T>A p.L1342Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100122785; called by muse, mutect2, varscan2
- RGS22 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100693155; called by muse, mutect2, varscan2
- RGS7 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as COSV100466376; called by muse, mutect2, varscan2
- RIMS4 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100865105; called by muse, mutect2, varscan2
- RIOX2 | c.1306A>T p.I436F (on ENST00000333396 / NM_001042533.2; = p.I435F on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99476873; called by muse, mutect2, varscan2
- RNASE11 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1286226876, COSV100250491; called by muse, mutect2, varscan2
- RNF10 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100378594, COSV58047664; called by muse, mutect2, varscan2
- RNF213 | c.7018G>T p.V2340F | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100300226; called by muse, mutect2, varscan2
- ROBO2 | c.143C>A p.T48K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV59893559, COSV59899603; called by muse, mutect2, varscan2
- ROBO4 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100127470; called by muse, mutect2, varscan2
- ROR1 | c.1175-1G>T p.X392_splice | Splice Site (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100935141; called by muse, mutect2, varscan2
- RPS6KC1 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100873849; called by muse, mutect2, varscan2
- RREB1 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.122); catalogued as COSV100619279; called by muse, mutect2, varscan2
- RSAD2 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761701524, COSV101149826; called by muse, mutect2
- RTL9 | c.3217C>A p.L1073I | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); catalogued as COSV101511662; called by muse, mutect2, varscan2
- RTP2 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV64079216; called by muse, mutect2, varscan2
- RYR2 | c.2987T>C p.V996A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as COSV100769426; called by muse, mutect2, varscan2
- RYR2 | c.3365G>T p.C1122F | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV63670469; called by muse, mutect2
- RYR3 | c.7447C>A p.Q2483K (on ENST00000389232; = p.Q2484K on NM_001036.6) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV101212476; called by muse, mutect2, varscan2
- S100A7 | c.259C>A p.H87N | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100906722; called by muse, mutect2, varscan2
- SAMD4A | c.1681C>A p.L561I | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99200622; called by muse, mutect2, varscan2
- SCARA3 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV100106670; called by muse, mutect2, varscan2
- SCN1A | c.3961C>G p.L1321V (on ENST00000303395 / NM_001202435.3; = p.L1310V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100320052; called by muse, mutect2, varscan2
- SCN5A | c.1636G>T p.D546Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100347573; called by muse, mutect2, varscan2
- SDE2 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99682606; called by muse, mutect2
- SEL1L2 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.991); catalogued as COSV99532988; called by muse, mutect2, varscan2
- SELP | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.059); catalogued as COSV99739513; called by muse, mutect2
- SEMA5A | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV101227727, COSV101228693; called by muse, mutect2, varscan2
- SENP7 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100052893; called by muse, mutect2, varscan2
- SEPTIN4 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 48/439 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV100400301; called by muse, mutect2, varscan2
- SEPTIN9 | c.380C>T p.P127L (on ENST00000427177 / NM_001113491.2; = p.P109L on NM_006640.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs758106177, COSV100217795; called by muse, mutect2, varscan2
- SERPINA11 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100593978, COSV100594000; called by muse, mutect2
- SERPINA6 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100448231; called by muse, mutect2
- SERPINB2 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV100208331; called by muse, mutect2, varscan2
- SERTAD4 | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100882600; called by muse, mutect2, varscan2
- SERTAD4 | c.460T>A p.C154S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100882601; called by muse, mutect2
- SETBP1 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99952779; called by muse, mutect2, varscan2
- SETD3 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100074987; called by muse, mutect2
- SGO2 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV100764650; called by mutect2, varscan2
- SIGLEC10 | c.901T>C p.W301R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV100218777; called by muse, mutect2
- SIGLEC8 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100367224; called by muse, mutect2, varscan2
- SIPA1L2 | c.4306G>T p.V1436L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV99477888; called by muse, mutect2, varscan2
- SIPA1L2 | c.3590G>A p.R1197K | Missense Mutation (SNP) | VAF 65/634 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99477891; called by muse, mutect2, varscan2
- SIRPD | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs139039354, COSV67547239; called by muse, mutect2
- SLAMF7 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100833251, COSV104420958; called by muse, mutect2, varscan2
- SLC14A1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100424976; called by muse, mutect2, varscan2
- SLC15A2 | c.780+1G>T p.X260_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99815391; called by muse, mutect2, varscan2
- SLC22A10 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV100235677; called by muse, mutect2, varscan2
- SLC22A2 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754226685, COSV100870970; called by muse, mutect2, varscan2
- SLC23A2 | c.908G>C p.W303S | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.636); catalogued as COSV100594949; called by muse, mutect2, varscan2
- SLC26A2 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773246028, COSV99640103; called by muse, mutect2
- SLC30A9 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100048119; called by muse, mutect2, varscan2
- SLC32A1 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV54146719, COSV99462079; called by muse, mutect2, varscan2
- SLC35B1 | c.556G>T p.A186S (on ENST00000649906; = p.A149S on NM_005827.4) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99539427; called by muse, mutect2, varscan2
- SLC35F1 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as COSV100837707; called by muse, mutect2, varscan2
- SLC36A3 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100077511; called by muse, mutect2, varscan2
- SLC4A1 | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99293229; called by muse, mutect2, varscan2
- SLC4A11 | c.2315T>C p.L772P | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101195933; called by muse, mutect2, varscan2
- SLC8A3 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751491505, COSV100776083; called by muse, mutect2, varscan2
- SLCO1A2 | c.302T>A p.F101Y | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV100261645; called by muse, mutect2, varscan2
- SLCO4A1 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1304788011, COSV99414656; called by muse, varscan2
- SLCO4C1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100194778; called by muse, mutect2, varscan2
- SLIT2 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99882823; called by muse, mutect2, varscan2
- SLITRK3 | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53846016; called by muse, mutect2, varscan2
- SLTM | c.3064G>T p.G1022* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100998626, COSV65848772; called by muse, mutect2, varscan2
- SMAP1 | c.667G>T p.G223C (on ENST00000370455 / NM_001044305.3; = p.G196C on NM_021940.5) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs748894950, COSV100016820; called by muse, mutect2, varscan2
- SMG1 | c.4264A>T p.M1422L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101245637; called by muse, mutect2, varscan2
- SMR3B | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100513358; called by muse, mutect2, varscan2
- SNX27 | c.802-1G>T p.X268_splice | Splice Site (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100919014; called by muse, mutect2
- SOBP | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV100433021; called by muse, mutect2, varscan2
- SORCS1 | c.538T>A p.W180R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99545239; called by muse, mutect2, varscan2
- SOS2 | c.2909A>T p.Q970L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV99365839; called by muse, mutect2, varscan2
- SOX30 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99398334; called by muse, mutect2, varscan2
- SPANXC | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV62842266, COSV62842345; called by muse, mutect2
- SPANXD | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV65152280; called by muse, mutect2, varscan2
- SPART | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100768665; called by muse, mutect2, varscan2
- SPEF2 | c.1375A>T p.M459L | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV56801695; called by muse, mutect2, varscan2
- SPEM1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371446830, COSV100080955, COSV100081271; called by muse, mutect2, varscan2
- SPHKAP | c.4367C>A p.A1456E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as COSV100764004; called by muse, mutect2, varscan2
- SPOCK1 | c.591C>A p.A197= | Splice Region (SNP) | VAF 8/69 reads (12%) | catalogued as COSV56437356, COSV99968580; called by muse, mutect2, varscan2
- SPRR2E | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV100907428; called by muse, mutect2, varscan2
- SPTA1 | c.2620G>T p.V874F | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100934709; called by muse, mutect2, varscan2
- SPTBN5 | c.3315G>T p.Q1105H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100311142; called by muse, mutect2, varscan2
- SRRM4 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99938269; called by muse, mutect2
- SRSF7 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100492595; called by muse, mutect2, varscan2
- ST18 | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99389147; called by muse, mutect2, varscan2
- ST3GAL5 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100088350; called by muse, mutect2, varscan2
- ST8SIA6 | c.697G>T p.V233L | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101112122; called by muse, mutect2
- STAG1 | c.2347G>A p.V783I | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1262416034, COSV99365107; called by muse, mutect2, varscan2
- STON2 | c.2329C>T p.L777F (on ENST00000649389 / NM_001366849.2; = p.L720F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as COSV99964629; called by muse, mutect2
- STRA6 | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.117); catalogued as COSV99997268; called by muse, mutect2, varscan2
- STRIP1 | c.1253G>A p.C418Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100873956; called by muse, mutect2, varscan2
- STT3A | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101205158; called by muse, mutect2, varscan2
- STX7 | c.742G>T p.G248* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100908426; called by muse, mutect2
- SUGP1 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99894905; called by muse, mutect2, varscan2
- SULF1 | c.256A>T p.M86L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99482759; called by muse, mutect2, varscan2
- SULF1 | c.1834G>T p.V612F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99482760; called by muse, mutect2, varscan2
- SV2C | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100455990; called by muse, mutect2
- SYNE2 | c.14774G>T p.W4925L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs773340630, COSV100647371; called by muse, mutect2, varscan2
- SYTL4 | c.354G>T p.W118C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294442024, COSV52170451, COSV99342813; called by muse, mutect2, varscan2
- TAB3 | c.1541A>G p.Y514C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99916105; called by muse, mutect2, varscan2
- TAF1L | c.2323A>T p.K775* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV99644465; called by muse, mutect2, varscan2
- TAS2R60 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV100223516; called by muse, mutect2, varscan2
- TASOR | c.2744G>A p.W915* (on ENST00000355628 / NM_001365636.2; = p.W519* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100843490; called by muse, mutect2, varscan2
- TBR1 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs199700587, COSV101271448; called by muse, mutect2, varscan2
- TCERG1 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV57036884, COSV99694680; called by muse, mutect2, varscan2
- TCHH | c.5540C>A p.A1847E | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV100914967, COSV100915119; called by muse, mutect2, varscan2
- TCTN2 | c.1784A>T p.N595I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100315168; called by muse, mutect2, varscan2
- TDP1 | c.1770G>C p.W590C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100187720; called by muse, mutect2
- TENM2 | c.980C>A p.T327K (on ENST00000518659 / NM_001122679.2; = p.T136K on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101318460; called by muse, mutect2, varscan2
- TENM2 | c.2739T>A p.D913E (on ENST00000518659 / NM_001122679.2; = p.D681E on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV101318461; called by muse, mutect2, varscan2
- TENM4 | c.3287C>A p.A1096E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774139090, COSV99573212; called by muse, mutect2, varscan2
- TESK1 | c.1804G>T p.G602C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99427379; called by muse, mutect2, varscan2
- TEX35 | c.585G>T p.R195= | Splice Region (SNP) | VAF 21/198 reads (11%) | catalogued as COSV51107260, COSV99274346; called by muse, mutect2, varscan2
- TEX47 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1323382520, COSV99787245; called by muse, mutect2, varscan2
- TFPI2 | c.289del p.R97Gfs*4 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | catalogued as COSV55990940; called by mutect2, pindel, varscan2
- TG | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99600216; called by muse, mutect2, varscan2
- TG | c.3434-1G>T p.X1145_splice | Splice Site (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99600219; called by muse, mutect2, varscan2
- TG | c.7516C>A p.L2506M | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55093729, COSV99600222; called by muse, mutect2, varscan2
- THBS2 | c.2219G>T p.C740F | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100827807; called by muse, mutect2, varscan2
- THNSL1 | c.81A>T p.K27N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV100896164; called by muse, mutect2, varscan2
- THOC2 | c.2792G>T p.C931F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.102); catalogued as COSV99833098; called by muse, mutect2, varscan2
- THSD7B | c.2006C>A p.P669H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55665029, COSV99748271; called by muse, mutect2, varscan2
- THSD7B | c.3532C>A p.L1178M (on ENST00000272643; = p.L1176M on NM_001316349.2) | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99748274; called by muse, mutect2, varscan2
- THTPA | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as rs1167317023, COSV99846147; called by muse, mutect2, varscan2
- TIAM1 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734315; called by muse, mutect2, varscan2
- TLL1 | c.1433A>T p.Y478F | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV99286855; called by muse, mutect2, varscan2
- TLL2 | c.2719C>A p.Q907K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as COSV100780230; called by muse, mutect2, varscan2
- TLR9 | c.2915G>A p.S972N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs1418858521, COSV100645604; called by muse, mutect2
- TMEFF1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100614597; called by muse, mutect2, varscan2
- TMEM132E | c.1906C>A p.L636I (on ENST00000321639; = p.L726I on NM_001304438.2) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.584); catalogued as rs779867137, COSV100396129; called by muse, mutect2, varscan2
- TMPRSS11A | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 32/153 reads (21%) | catalogued as rs764749590, COSV58359980; called by muse, mutect2, varscan2
435 further variants in this file (149 protein-altering or splice-affecting, 252 silent, 34 other) are not listed here.
